Surgical pathology report (de-identified scan), TCGA case TCGA-UD-AABY, project TCGA-MESO (Mesothelioma), tissue source site  University of Western Australia, specimen TCGA-UD-AABY-01A (Primary Tumor).

[page 1 of 3]
Requested by :

Sex : Male

DOB :

Request :

Service Date :

Service Time :

CYTOLOGY

LABORATORY NUMBER:

SPECIMEN:
PLEURAL EFFUSION.

MACROSCOPIC:
500ml of translucent yellow/orange fluid received. Two alcohol fixed smears and two air dried smears prepared.

MICROSCOPIC:
The smears are highly cellular and contain numerous balls and crowded clusters of cells in a background of histiocytes, mesothelial cells and lymphocytes. The cells within the balls have small oval nuclei. Some cell in cell clustering is present. Occasional cells have vacuolated cytoplasm. In some of the papillary clusters there is a central core of fibrous tissue. The cell block is also cellular and contains numerous clusters of cells, some of which have a central fibrous core. Immunoperoxidase staining for Cytokeratin and EMA are positive and for CEA is negative. The cells contain glycogen and mucin is not seen.

Pathologist :
Report Date :

All Enquiries

D
O
C
T
O
R

P
A
T
I
E
N
T

Sex: Male

DOB:

Request :
Service Date :
Service Time :

CONCLUSION:
The cytologic features are those of a malignant effusion and are consistent with malignant mesothelioma. A portion of the specimen has been reserved in glutaraldehyde and will be sent for electron microscopic confirmation of the diagnosis.

Pr TSS, 100% epithelioid.

Bca

*CHF ICD-O-3
Mesothelioma, epithelioid
malignant 9052/3
path Mesothelioma, malignant 9050/3
Site: Pleura NOS C38.4
9/29/14*

[page 2 of 3]
From:

To:

Anatomical Pathology ELECTRON MICROSCOPY

	:		:
PATIENT	:	LAB. NO.	:
ADDRESS	:		
SEX	:	WARD	:
D.O.B.	:	REQUEST DATE	:
DOCTOR	:	CONSULTANT	:

SPECIMEN:

Pleural fluid

ELECTRON MICROSCOPY:

As noted in the cytological preparations, there are clusters of mesothelial cells, sometimes associated with a central collagenous core, forming small papillary structures. The cells have moderately irregular nuclei and some possess prominent nucleoli. The free surfaces of the cells show well-formed, long and thin microvilli devoid of glycocalyx and lacking any filamentous core rootlets. These microvillous are slender, wavy and often branched. Apically the cells are joined by well formed junctional complexes. In the cytoplasm, there are perinuclear intermediate filaments arranged as tonofilaments and some of these insert into well formed desmosomes. There are small collections of rosetted glycogen in the cytoplasm. Other organelles are non-specifically distributed. There are no mucin granules evident.

CONCLUSION:

Pleural fluid – The ultrastructural characteristics are in keeping with a malignant mesothelioma.

PATHOLOGIST:

ELECTRON MICROSCOPY REPORT

Diagnostic Discrepancy		

[page 3 of 3]
TCGA Pathologic Diagnosis Discrepancy Form

V4.00

Instructions: The TCGA Pathologic Diagnosis Discrepancy Form should be completed when the pathologic diagnosis documented on the initial pathology report for a case submitted for TCGA is inconsistent with the diagnosis provided on the Case Quality Control Form completed for the submitted case.

Tissue Source Site (TSS): _____ TSS Identifier: _____ TSS Unique Patient Identifier: _____

Completed By (Interviewer Name on OpenClinica): _____ Completed Date: _____

Diagnosis Information

#	Data Element	Entry Alternatives	Working Instructions
1	Pathologic Diagnosis Provided on Initial Pathology Report	not specified	Provide the diagnosis/ histologic subtype(s) documented on the initial pathology report for this case. If the histology for this case is mixed, provide all listed subtypes.
2	Histologic features of the sample provided for TCGA, as reflected on the CQCF.	epithelial	Provide the histologic features selected on the TCGA Case Quality Control Form completed for this case.

Discrepancy between Pathology Report and Case Quality Control Form

3	Provide the reason for the discrepancy between the pathology report and the TCGA Case Quality Control Form.	Original pathology report was made upon a cytology specimen. No official pathology report issued for biopsy. Review of FFPE by pathologist determined histology to be epithelial.	Provide a reason describing why the diagnosis on the initial pathology report for this case is not consistent with the diagnosis selected on the TCGA Case Quality Control Form.
4	Name of TSS Reviewing Pathologist or Biorepository Director	_____	Provide the name of the pathologist who reviewed this case for TCGA.

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled.

TSS Reviewing Pathologist or Biorepository Director

Date

I acknowledge that the above information provided by my institution is true and correct and has been quality controlled. The Attending Pathologist or the Department Chairman has been informed or is aware of the above discrepancy in diagnoses.

Principal Investigator Signature

Date

Source: NCI Genomic Data Commons file fd462e7e-aab6-49e2-b9ae-c8e17828d764 (TCGA-UD-AABY.BED6A020-507B-41BD-8658-C092DBC9F369.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).